Surgical pathology report (de-identified scan), TCGA case TCGA-58-8386, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8386-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED]

Pathology Report-Summary:

Material 1:

lung, right, upper lobe, 18 x 10 x 5 cm

central tumor, 4.2 x 3 x 3.5 cm

Material 2:

lung, right, Se7, 5 x 2.5 x 2.5 cm

tumor, 2.8 x 2.2 x 1.6 cm (metastasis of tumor from material1)

Diagnosis:

Squamous Cell Carcinoma (NOS)

Infiltration of pleura visceralis and pleura parietalis

Metastasis in lower lobe, right

pT3, pNx (0/10), pM1 (lung), G3

[REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 706f2a29-ea40-4321-aae6-4b2384ec4b34 (TCGA-58-8386.F239EA75-1EBB-48AC-AB2A-10669E72A24D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).